Somatic mutation profile of tumor specimen TCGA-JW-A5VL-01A (aliquot TCGA-JW-A5VL-01A-11D-A28B-09) from TCGA case TCGA-JW-A5VL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G1; Age at diagnosis: 37.2 years (13,604 days).
Specimen TCGA-JW-A5VL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2b02729-4280-4914-8d37-964d9168aa86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JW-A5VL-10A (Blood Derived Normal), aliquot TCGA-JW-A5VL-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66b89c4c-6990-4430-bddf-1e376506603e

The open-access MAF lists 2,258 somatic variants for this specimen: 1,668 protein-altering or splice-affecting, 532 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,491, Silent 532, Nonsense Mutation 140, Intron 22, Splice Site 15, RNA 12, Splice Region 10, 5'UTR 9, 3'UTR 6, Frame Shift Ins 6, 5'Flank 6, Translation Start Site 3.

Variants (750 of 2,258; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs397517065, COSV51762486; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BARD1 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as rs776851287; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CASR | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs121909259, CM930078, COSV56137950, COSV99072547; ClinVar: pathogenic; called by muse, varscan2
- FOXL2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 48/180 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM082718, COSV57725966, COSV57728681; called by muse, mutect2, varscan2
- MGME1 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs587776943, CM130787, COSV66624077; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SASH1 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs587781245, CM155722, COSV66560894; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AAMP | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV50307378; called by muse, mutect2, varscan2
- ABCA12 | c.2403G>C p.L801F (on ENST00000272895 / NM_173076.3; = p.L483F on NM_015657.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55955401; called by muse, mutect2, varscan2
- ABCA12 | c.1393G>A p.E465K (on ENST00000272895 / NM_173076.3; = p.E147K on NM_015657.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs866784560; called by muse, mutect2
- ABCA13 | c.11700C>G p.I3900M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs775755386; called by muse, mutect2, varscan2
- ABCA7 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1274398568; called by muse, mutect2, varscan2
- ABCA9 | c.2660C>G p.S887* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV60623408; called by muse, mutect2, varscan2
- ABCB5 | c.3080G>A p.R1027H (on ENST00000404938 / NM_001163941.2; = p.R582H on NM_178559.6) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs745749100, COSV51703658, COSV51718688; called by muse, varscan2
- ABCC10 | c.379C>G p.H127D (on ENST00000372530 / NM_001198934.2; = p.H84D on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV55086653; called by muse, mutect2, varscan2
- ABHD2 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV61775755; called by muse, mutect2, varscan2
- ABHD8 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV56043869, COSV56046304; called by muse, mutect2, varscan2
- AC100868.1 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.198); catalogued as COSV51841073; called by muse, mutect2, varscan2
- ACAA2 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV53270482; called by muse, mutect2, varscan2
- ACADM | c.462G>C p.L154F | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV63720142; called by muse, mutect2, varscan2
- ACAT1 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777462355; called by muse, mutect2, varscan2
- ACKR3 | c.252G>C p.L84F | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV56021282; called by muse, mutect2, varscan2
- ACOT9 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as COSV60537399; called by muse, mutect2, varscan2
- ACOX1 | c.1526G>A p.R509K | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV53132767; called by muse, mutect2, varscan2
- ACOX2 | c.1464G>C p.Q488H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV57148506; called by muse, mutect2, varscan2
- ACSS3 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV54086888, COSV54087221, COSV54089111; called by muse, mutect2, varscan2
- ACTL10 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV55775627, COSV99864534; called by muse, mutect2
- ACTL6A | c.630C>G p.F210L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV66998864; called by muse, mutect2, varscan2
- ACTR1B | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV56703073, COSV56703912; called by muse, mutect2, varscan2
- ACTR6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 28/73 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV51841619, COSV51841650; called by muse, mutect2, varscan2
- ACTR6 | c.1136G>A p.R379K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.063); catalogued as COSV51841641; called by muse, mutect2, varscan2
- ACVR2A | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as COSV54021171; called by muse, mutect2, varscan2
- ADAM32 | c.2263C>G p.Q755E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.03); catalogued as rs1184740702; called by muse, mutect2, varscan2
- ADAM9 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.629); catalogued as COSV65946634; called by muse, mutect2, varscan2
- ADAM9 | c.605G>C p.R202P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65946572, COSV65946664, COSV65946805; called by muse, mutect2, varscan2
- ADAMTS12 | c.2425G>C p.E809Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.896); catalogued as COSV61260604; called by muse, mutect2, varscan2
- ADAMTS15 | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54504672; called by muse, mutect2, varscan2
- ADAMTS17 | c.2292G>C p.L764F | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs577389531, COSV51477728; called by muse, mutect2, varscan2
- ADAMTS20 | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67130094; called by muse, mutect2, varscan2
- ADAMTS6 | c.2290G>C p.D764H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV66858823; called by muse, varscan2
- ADAMTS6 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66858826; called by muse, mutect2, varscan2
- ADARB1 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV62342613, COSV62343666; called by muse, mutect2, varscan2
- ADCY2 | c.2692G>C p.E898Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV99059536; called by muse, mutect2, varscan2
- ADCY8 | c.2121G>C p.M707I | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.437); catalogued as COSV53909565; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58445166; called by muse, mutect2, varscan2
- ADGRA1 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV101658627; called by muse, mutect2, varscan2
- ADGRB2 | c.2936C>G p.S979C | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314407928; called by muse, mutect2, varscan2
- ADGRF3 | c.2003C>T p.S668L (on ENST00000311519 / NM_001145168.1; = p.S469L on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV100275205; called by muse, mutect2, varscan2
- ADGRF3 | c.1888C>T p.R630W (on ENST00000311519 / NM_001145168.1; = p.R431W on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs772019536, COSV61049779; called by muse, mutect2, varscan2
- ADGRG5 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV61083043; called by muse, mutect2, varscan2
- ADGRV1 | c.9130C>G p.Q3044E | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as COSV67983279, COSV67985701; called by muse, mutect2, varscan2
- AFDN | c.3808C>G p.Q1270E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.08); catalogued as COSV100653056; called by muse, mutect2, varscan2
- AFG1L | c.1305G>C p.L435F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64555429; called by muse, mutect2, varscan2
- AHNAK2 | c.8152G>C p.E2718Q | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV60912947; called by muse, mutect2, varscan2
- AIFM3 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 40/88 reads (45%) | catalogued as COSV58998733; called by muse, mutect2, varscan2
- AIFM3 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.01); catalogued as COSV58998755; called by muse, mutect2
- AIRE | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778067704, COSV52392624; called by muse, mutect2
- AK8 | c.558G>C p.E186D | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV53752826; called by muse, mutect2, varscan2
- AKNA | c.3978G>A p.W1326* | Nonsense Mutation (SNP) | VAF 47/78 reads (60%) | catalogued as COSV56336319; called by muse, mutect2, varscan2
- AKTIP | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV50875482; called by muse, mutect2, varscan2
- AKTIP | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752514939, COSV50875484; called by muse, mutect2, varscan2
- AL358113.1 | c.3353C>T p.P1118L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1288468467; called by muse, mutect2, varscan2
- AL592490.1 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs559148086, COSV69425665; called by muse, mutect2, varscan2
- ALDH1B1 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV66619709; called by muse, mutect2, varscan2
- ALDOA | c.1154G>C p.R385P (on ENST00000642816 / NM_001243177.4; = p.R331P on NM_184041.5) | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57632442; called by muse, varscan2
- ALG1 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52157241; called by muse, mutect2, varscan2
- ALG6 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV54764513; called by muse, mutect2, varscan2
- ALK | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1453170969, COSV66564584, COSV66584134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK3 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs142197641, COSV51931467; called by muse, mutect2, varscan2
- ALPK3 | c.3641C>G p.S1214C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51932353; called by muse, mutect2, varscan2
- AMD1 | c.325-1G>C p.X109_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100924461, COSV64387244; called by muse, mutect2, varscan2
- AMHR2 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 34/59 reads (58%) | catalogued as COSV57684780; called by muse, mutect2, varscan2
- AMPD1 | c.1428C>G p.F476L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs766228935, COSV62415554, COSV62415706, COSV62416040; called by muse, mutect2, varscan2
- ANK2 | c.187-1G>C p.X63_splice | Splice Site (SNP) | VAF 18/41 reads (44%) | catalogued as COSV52156250; called by muse, mutect2, varscan2
- ANK2 | c.8569G>C p.E2857Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.066); catalogued as COSV52144197, COSV52156267, COSV52176732; called by muse, mutect2, varscan2
- ANK3 | c.6391G>C p.E2131Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55053323, COSV55058299; called by muse, mutect2, varscan2
- ANKFN1 | c.1703C>G p.S568* | Nonsense Mutation (SNP) | VAF 31/52 reads (60%) | catalogued as COSV100593343; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3046C>T p.Q1016* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV51845014; called by muse, mutect2, varscan2
- ANKRD26 | c.4858G>A p.D1620N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as COSV65774959; called by muse, mutect2, varscan2
- ANKRD44 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as rs369157403; called by muse, mutect2, varscan2
- ANLN | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV56075621, COSV99733036; called by muse, mutect2, varscan2
- ANO10 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV52730189; called by muse, mutect2, varscan2
- ANO2 | c.2553C>G p.F851L (on ENST00000356134 / NM_001278597.3; = p.F855L on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59017654; called by muse, mutect2, varscan2
- AOX1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs760528585, COSV65981119; called by muse, mutect2, varscan2
- AOX1 | c.3589C>T p.P1197S | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53495788; called by muse, mutect2, varscan2
- AP002748.5 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV59148105; called by muse, mutect2, varscan2
- AP2B1 | c.714G>C p.Q238H | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV51998641; called by muse, mutect2, varscan2
- APAF1 | c.3470C>G p.S1157* (on ENST00000551964 / NM_181861.2; = p.S1103* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV59663402; called by muse, mutect2, varscan2
- APOB | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs1271356302; called by muse, mutect2, varscan2
- APOBEC1 | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as COSV57548511; called by muse, mutect2, varscan2
- AQR | c.3796C>T p.Q1266* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV50032091; called by muse, mutect2, varscan2
- ARFGEF1 | c.3799C>G p.Q1267E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51613996, COSV99144732; called by muse, mutect2, varscan2
- ARFGEF3 | c.5108G>A p.G1703E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1461088358; called by muse, mutect2, varscan2
- ARHGAP45 | c.2465C>A p.S822* | Nonsense Mutation (SNP) | VAF 44/90 reads (49%) | catalogued as COSV57431021; called by muse, mutect2, varscan2
- ARHGEF11 | c.2628C>G p.I876M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV59353692; called by muse, mutect2, varscan2
- ARHGEF16 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV65681779; called by muse, varscan2
- ARHGEF17 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV55231616; called by muse, mutect2
- ARID1A | c.4009G>A p.D1337N | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs1310778455; called by muse, mutect2, varscan2
- ARID3A | c.947C>G p.T316S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV55044119; called by muse, mutect2, varscan2
- ARID3B | c.1637C>T p.S546L (on ENST00000622429 / NM_001307939.1; = p.S545L on NM_006465.4) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs747206512, COSV60557325; called by muse, mutect2, varscan2
- ARMCX3 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57870163; called by muse, varscan2
- ART4 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV57451679; called by muse, mutect2, varscan2
- ASPH | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV65243869, COSV65244144; called by muse, mutect2, varscan2
- ATG2A | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV65966379; called by muse, mutect2, varscan2
- ATG2A | c.1130C>A p.S377* | Nonsense Mutation (SNP) | VAF 51/117 reads (44%) | catalogued as COSV104425997; called by muse, mutect2, varscan2
- ATM | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1196453563, COSV53732018; ClinVar: uncertain significance; called by muse, varscan2
- ATP13A4 | c.1789C>T p.H597Y | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); catalogued as rs756102686, COSV55068346; called by muse, mutect2, varscan2
- ATP13A5 | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100665905, COSV60867553; called by muse, mutect2, varscan2
- ATP2A2 | c.2598C>G p.F866L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs538399392, COSV57875347; called by muse, mutect2, varscan2
- ATP5PF | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV57256875; called by muse, mutect2, varscan2
- ATP7B | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as COSV54437383; called by muse, mutect2, varscan2
- ATP8B2 | c.750G>A p.W250* (on ENST00000672630; = p.W217* on NM_001005855.2) | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV100527904; called by muse, mutect2, varscan2
- ATRAID | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV60159110; called by muse, mutect2, varscan2
- ATXN1 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55213910; called by muse, mutect2
- AVIL | c.476G>C p.R159P | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as COSV57681447, COSV57683092; called by muse, mutect2, varscan2
- BAG4 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV54860881, COSV99782106; called by muse, mutect2, varscan2
- BAG5 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.136); catalogued as COSV54570679, COSV54570780; called by muse, mutect2, varscan2
- BAHCC1 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV57025276; called by muse, mutect2, varscan2
- BATF3 | c.327G>C p.M109I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54658252; called by muse, mutect2, varscan2
- BBS2 | c.2038C>G p.Q680E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99803008; called by muse, mutect2, varscan2
- BBS7 | c.1787-1G>C p.X596_splice | Splice Site (SNP) | VAF 9/19 reads (47%) | catalogued as CS155253, COSV52655735; called by muse, mutect2, varscan2
- BCLAF1 | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100786792, COSV62141551; called by muse, mutect2, varscan2
- BCOR | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV60704890, COSV60705153; called by muse, mutect2, varscan2
- BCORL1 | c.4578G>A p.M1526I | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV54394129; called by muse, mutect2, varscan2
- BDH1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV64018306; called by muse, mutect2, varscan2
- BEGAIN | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100766993, COSV62068543; called by muse, mutect2, varscan2
- BEND3 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs782375289, COSV64680809; called by muse, mutect2, varscan2
- BEND7 | c.479C>G p.S160* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV61988353; called by muse, mutect2, varscan2
- BFAR | c.1182G>C p.W394C | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746810685; called by muse, mutect2, varscan2
- BIRC3 | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV54816191, COSV54816586; called by muse, mutect2, varscan2
- BLNK | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV56414460; called by muse, mutect2, varscan2
- BLVRA | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.188); catalogued as COSV99646175; called by muse, mutect2, varscan2
- BMP15 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53140292; called by muse, mutect2, varscan2
- BMX | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.349); catalogued as COSV59591071; called by muse, mutect2, varscan2
- BNC2 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV66144994; called by muse, mutect2, varscan2
- BNIP3 | c.638C>G p.T213R | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64043795; called by muse, mutect2, varscan2
- BPTF | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58835369; called by muse, mutect2, varscan2
- BRD2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255464557; called by muse, mutect2, varscan2
- BRIP1 | c.3457G>C p.D1153H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.152); catalogued as COSV51997827, COSV52010658; called by muse, mutect2, varscan2
- BSG | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61076741; called by muse, mutect2, varscan2
- BST2 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.129); catalogued as COSV53088923; called by muse, mutect2, varscan2
- BTLA | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.13); catalogued as COSV57938117; called by muse, mutect2, varscan2
- BTN3A2 | c.936C>T p.L312= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as rs766000909, COSV62687113; called by muse, mutect2, varscan2
- BTN3A3 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776296722; called by muse, mutect2, varscan2
- C12orf60 | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV57451670; called by muse, mutect2, varscan2
- C1QTNF6 | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55396212; called by muse, mutect2, varscan2
- C20orf27 | c.208C>G p.L70V (on ENST00000379772 / NM_001258429.2; = p.L95V on NM_001039140.3) | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.203); catalogued as COSV53925449, COSV99422098; called by muse, mutect2, varscan2
- C2CD2L | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV60883902; called by muse, mutect2, varscan2
- C2CD3 | c.2130C>G p.I710M | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV58092425; called by muse, mutect2, varscan2
- C5AR1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61892443; called by muse, mutect2, varscan2
- CACNA1A | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1469683674, COSV100801971, COSV64195535; called by muse, mutect2, varscan2
- CACNA1B | c.411C>G p.F137L | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53127963; called by muse, mutect2, varscan2
- CACNA1G | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs1363009203, COSV61724626; called by muse, mutect2, varscan2
- CACNA1H | c.7019C>G p.S2340* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV52354033; called by muse, mutect2, varscan2
- CACNA2D2 | c.2690G>C p.G897A (on ENST00000479441 / NM_001174051.3; = p.G890A on NM_006030.4) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99818549; called by muse, mutect2, varscan2
- CALCB | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60834368; called by muse, mutect2, varscan2
- CALCOCO1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.542); catalogued as rs1386950347, COSV50413233; called by muse, mutect2, varscan2
- CAPN1 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.219); catalogued as rs1476322417; called by muse, mutect2, varscan2
- CAPS2 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV60824904; called by muse, mutect2, varscan2
- CASP3 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.585); catalogued as COSV57724975; called by muse, mutect2, varscan2
- CASP8AP2 | c.5194G>C p.D1732H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV52746379; called by muse, mutect2, varscan2
- CASR | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs199729084, COSV56133767, COSV56136578; called by muse, varscan2
- CASR | c.2068G>A p.E690K (on ENST00000490131; = p.E767K on NM_000388.4) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.994); catalogued as CM050191, CM106568, COSV56136585, COSV99949724; called by muse, mutect2, varscan2
- CATSPERG | c.2758C>G p.L920V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV53047873; called by muse, mutect2, varscan2
- CBFA2T2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV60798309; called by muse, mutect2, varscan2
- CCDC18 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV58142629; called by muse, mutect2, varscan2
- CCDC186 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as COSV100991057; called by muse, mutect2, varscan2
- CCDC38 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.796); catalogued as COSV100717507, COSV60182809; called by muse, mutect2, varscan2
- CCDC63 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV57530006; called by muse, mutect2, varscan2
- CCNT2 | c.818C>G p.S273* | Nonsense Mutation (SNP) | VAF 31/94 reads (33%) | catalogued as COSV51472370; called by muse, mutect2, varscan2
- CCR1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56121990; called by muse, mutect2, varscan2
- CD200 | c.637C>G p.H213D (on ENST00000473539 / NM_001004196.3; = p.H188D on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV59862793; called by muse, mutect2, varscan2
- CD36 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV59212014; called by muse, mutect2, varscan2
- CD96 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV51915154; called by muse, mutect2, varscan2
- CDC25B | c.718G>C p.D240H (on ENST00000245960 / NM_021873.3; = p.D226H on NM_004358.4) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as rs751070261; called by muse, varscan2
- CDC25B | c.802G>C p.D268H (on ENST00000245960 / NM_021873.3; = p.D254H on NM_004358.4) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55655720; called by muse, varscan2
- CDC42BPB | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as COSV63474689; called by muse, varscan2
- CDC42BPG | c.4313C>T p.S1438L | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1046811787; called by muse, mutect2, varscan2
- CDC42BPG | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.642); catalogued as COSV61346785; called by muse, mutect2, varscan2
- CDC42EP1 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as rs368492182; called by muse, mutect2, varscan2
- CDH12 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs773955386, COSV101203443, COSV101203477; called by muse, mutect2, varscan2
- CDH12 | c.828G>C p.L276F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs910105365; called by muse, mutect2, varscan2
- CDH13 | c.99G>C p.Q33H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV51809702; called by muse, mutect2, varscan2
- CDH15 | c.592A>G p.S198G | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1488956477, COSV57023512; called by muse, mutect2, varscan2
- CDK13 | c.2340C>G p.F780L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99475207; called by muse, mutect2
- CDK14 | c.284C>G p.S95C (on ENST00000380050 / NM_001287135.2; = p.S77C on NM_012395.3) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV56031556; called by muse, mutect2, varscan2
- CDON | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV54996997, COSV54997745; called by muse, mutect2
- CDR2L | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 71/105 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61500927; called by muse, mutect2, varscan2
- CDT1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1444682337, COSV99967084; called by muse, mutect2, varscan2
- CEACAM6 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.331); catalogued as rs1452460745, COSV52269217; called by muse, mutect2, varscan2
- CEBPA | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1455027551, COSV57196964; called by muse, mutect2, varscan2
- CEMIP2 | c.2635C>T p.H879Y | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.171); catalogued as COSV65484557, COSV65484634; called by muse, mutect2, varscan2
- CEMIP2 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV65486704; called by muse, mutect2, varscan2
- CEMIP2 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV65486710; called by muse, mutect2, varscan2
- CENPE | c.4860G>A p.M1620I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1464002662; called by muse, mutect2, varscan2
- CENPF | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1339918274, COSV65274190; called by muse, mutect2, varscan2
- CENPF | c.2623C>G p.Q875E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as COSV65274196; called by muse, mutect2, varscan2
- CEP290 | c.3960G>C p.E1320D | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV100470251; called by muse, mutect2, varscan2
- CEP350 | c.3512C>G p.S1171C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV62601062; called by muse, mutect2, varscan2
- CEP44 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV99639880; called by muse, mutect2, varscan2
- CEP68 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV53124384; called by muse, mutect2, varscan2
- CERCAM | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs781104554, COSV65710786; called by muse, mutect2, varscan2
- CERS3 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV52567227, COSV52568348; called by muse, mutect2, varscan2
- CFAP100 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV61502825; called by muse, mutect2, varscan2
- CFAP221 | c.2494G>T p.A832S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV54656370; called by muse, mutect2, varscan2
- CFAP57 | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV65264215; called by muse, mutect2, varscan2
- CFAP65 | c.3519C>G p.F1173L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100446097, COSV58566179; called by muse, mutect2, varscan2
- CFAP74 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as rs749548320, COSV54566698; called by muse, mutect2, varscan2
- CFAP74 | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1400164215, COSV54566710; called by muse, mutect2, varscan2
- CFAP92 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV54047033; called by muse, mutect2, varscan2
- CFDP1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as COSV52208568; called by muse, mutect2, varscan2
- CFDP1 | c.403-1G>A p.X135_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as COSV52208578; called by muse, mutect2, varscan2
- CFHR5 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV56820703, COSV56821014; called by muse, mutect2, varscan2
- CHD1 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52339325; called by muse, mutect2, varscan2
- CHD4 | c.1354G>A p.D452N (on ENST00000357008 / NM_001363606.2; = p.D465N on NM_001273.5) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV58898967; called by muse, mutect2, varscan2
- CHD9 | c.4585G>A p.E1529K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54609437; called by muse, mutect2, varscan2
- CHGB | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs1460977058, COSV66760154; called by muse, mutect2, varscan2
- CHP1 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV58156839; called by muse, mutect2, varscan2
- CHRNA1 | c.567G>C p.M189I (on ENST00000261007 / NM_001039523.3; = p.M164I on NM_000079.4) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53682579; called by muse, mutect2, varscan2
- CIC | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.33); catalogued as COSV50558505; called by muse, mutect2, varscan2
- CKAP5 | c.5571G>C p.K1857N (on ENST00000529230 / NM_001008938.4; = p.K1797N on NM_014756.3) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56366723; called by muse, mutect2, varscan2
- CLCC1 | c.1427G>A p.G476E (on ENST00000356970 / NM_001377464.1; = p.G426E on NM_015127.5) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51442036; called by muse, mutect2, varscan2
- CLCN7 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as rs1253129482, CM130351; called by muse, mutect2, varscan2
- CLCNKA | c.1971C>G p.F657L | Missense Mutation (SNP) | VAF 130/148 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs541770891, COSV58890246, COSV58891202; called by muse, mutect2, varscan2
- CLDN16 | c.656C>G p.S219* | Nonsense Mutation (SNP) | VAF 38/162 reads (23%) | catalogued as COSV99290431; called by muse, mutect2, varscan2
- CLEC16A | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV101278564; called by muse, mutect2, varscan2
- CLEC4A | c.503C>G p.S168* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as rs1484860238, COSV57561615; called by muse, mutect2, varscan2
- CLNK | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57013736; called by muse, mutect2, varscan2
- CLPP | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55534832; called by muse, mutect2, varscan2
- CLTC | c.4408C>G p.L1470V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV52246838; called by muse, mutect2, varscan2
- CMKLR1 | c.751C>T p.R251C (on ENST00000312143 / NM_001142344.2; = p.R249C on NM_004072.3) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775282959, COSV56441057, COSV56442221; called by muse, mutect2, varscan2
- CMSS1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101375682; called by muse, mutect2
- CMYA5 | c.4439C>G p.S1480C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs962522223, COSV71409517; called by muse, mutect2, varscan2
- CNBD2 | c.1149-1G>A p.X383_splice | Splice Site (SNP) | VAF 22/51 reads (43%) | catalogued as COSV62586764; called by muse, mutect2, varscan2
- CNKSR1 | c.2093C>G p.S698C (on ENST00000374253 / NM_001297647.2; = p.S691C on NM_006314.3) | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV58792838; called by muse, mutect2, varscan2
- CNKSR2 | c.2280G>C p.K760N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.51); catalogued as COSV54253754; called by muse, mutect2, varscan2
- COBLL1 | c.1922C>A p.S641Y (on ENST00000392717; = p.S603Y on NM_014900.5) | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99528935; called by muse, mutect2, varscan2
- COG5 | c.2272G>C p.D758H (on ENST00000347053 / NM_001379512.1; = p.D779H on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51747910; called by muse, mutect2, varscan2
- COL14A1 | c.4229C>G p.S1410C | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52846287; called by muse, mutect2, varscan2
- COL1A1 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs35183627, COSV56808616; called by muse, mutect2, varscan2
- COL27A1 | c.3634G>C p.D1212H | Missense Mutation (SNP) | VAF 127/216 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV61924815; called by muse, mutect2, varscan2
- COL2A1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as CD021813; called by muse, mutect2, varscan2
- COL6A1 | c.1063C>G p.Q355E | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.219); catalogued as COSV100720102; called by muse, mutect2, varscan2
- COL6A1 | c.2474C>G p.S825C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV62612679; called by muse, mutect2, varscan2
- COL7A1 | c.3187C>G p.Q1063E | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs906583553; called by muse, mutect2, varscan2
- COL8A1 | c.1777G>C p.D593H | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV53732533; called by muse, mutect2, varscan2
- COPB2 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100300499; called by muse, mutect2
- COPG1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs1199837030, COSV59113593; called by muse, mutect2, varscan2
- CORO2A | c.871-1G>C p.X291_splice | Splice Site (SNP) | VAF 24/75 reads (32%) | catalogued as COSV59662843; called by muse, mutect2, varscan2
- CORO7 | c.2215G>C p.D739H | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52029258; called by muse, mutect2, varscan2
- COX4I1 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1415977775, COSV53665910; called by muse, mutect2, varscan2
- CPLANE2 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV65056593; called by muse, mutect2, varscan2
- CPLX1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV58375725, COSV58377226; called by muse, mutect2, varscan2
- CPSF1 | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58233253; called by muse, mutect2, varscan2
- CPT2 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53759048; called by muse, mutect2, varscan2
- CPXM1 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV66045068, COSV66045116; called by muse, mutect2, varscan2
- CRACD | c.504G>C p.Q168H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51723461; called by muse, mutect2, varscan2
- CREB5 | c.922C>T p.Q308* (on ENST00000357727 / NM_182898.4; = p.Q301* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 63/142 reads (44%) | catalogued as COSV63219582; called by muse, mutect2, varscan2
- CSKMT | c.545C>G p.S182* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100649041, COSV63472913; called by muse, mutect2, varscan2
- CSNK1D | c.1094G>C p.R365T | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV53923971; called by muse, mutect2, varscan2
- CST1 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59055994, COSV59056019; called by muse, mutect2, varscan2
- CTAGE1 | c.1757C>G p.S586* | Nonsense Mutation (SNP) | VAF 62/159 reads (39%) | catalogued as COSV66943048, COSV66943296; called by muse, mutect2
- CTAGE6 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV101417902; called by mutect2, varscan2
- CTCF | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV50465630; called by muse, mutect2, varscan2
- CX3CL1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1410783167; called by muse, mutect2, varscan2
- CYB5B | c.11C>G p.S4* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as COSV57174391; called by muse, mutect2, varscan2
- CYFIP1 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs772883059; called by muse, mutect2, varscan2
- CYP3A5 | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV56119467; called by muse, mutect2, varscan2
- CYRIA | c.955C>G p.R319G | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV62864431, COSV62864786; called by muse, mutect2, varscan2
- CYRIB | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV67829652, COSV67831737; called by muse, mutect2, varscan2
- CYRIB | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV67829655; called by muse, mutect2
- CYSLTR2 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs754435156; called by muse, mutect2, varscan2
- D2HGDH | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV58320235; called by muse, mutect2, varscan2
- DAAM1 | c.2103G>C p.S701= | Splice Region (SNP) | VAF 7/30 reads (23%) | catalogued as COSV62835664; called by muse, mutect2, varscan2
- DAAM2 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51309298; called by muse, mutect2, varscan2
- DAAM2 | c.3178G>C p.E1060Q (on ENST00000274867 / NM_001201427.2; = p.E1059Q on NM_015345.3) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1450714195, COSV51305211, COSV99227668; called by muse, varscan2
- DAP3 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV100546672, COSV58020152; called by muse, mutect2, varscan2
- DAXX | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs763046918, COSV56468354; called by muse, mutect2, varscan2
- DAXX | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as COSV56474010; called by muse, mutect2, varscan2
- DAZL | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); catalogued as COSV51712492; called by muse, mutect2, varscan2
- DCAF4L1 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV60787073; called by muse, mutect2, varscan2
- DCAF5 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.991); catalogued as COSV58459772; called by muse, mutect2, varscan2
- DCHS1 | c.9740C>T p.S3247L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs977153762, COSV54996660; called by muse, mutect2, varscan2
- DCT | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs759177137, COSV65468582; called by muse, mutect2, varscan2
- DDX20 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV63830976; called by muse, mutect2, varscan2
- DDX5 | c.1573G>C p.D525H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.477); catalogued as COSV104387750, COSV56748784; called by muse, mutect2, varscan2
- DENND3 | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs754976184, COSV52802080; called by muse, mutect2, varscan2
- DENND4A | c.2272C>G p.Q758E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.965); catalogued as COSV71267324; called by muse, mutect2, varscan2
- DGKG | c.2025G>C p.K675N | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV53963763, COSV99403344; called by muse, mutect2, varscan2
- DGKK | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1176170610; called by muse, mutect2, varscan2
- DGKZ | c.927G>C p.R309S (on ENST00000454345 / NM_001105540.2; = p.R120S on NM_003646.4) | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100552000; called by muse, mutect2, varscan2
- DHTKD1 | c.1729C>G p.L577V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV53802887, COSV53804985; called by muse, mutect2, varscan2
- DHX15 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.031); catalogued as COSV100391483, COSV61026517; called by muse, mutect2, varscan2
- DIP2B | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.317); catalogued as COSV56582095; called by muse, varscan2
- DIPK2A | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV59857096; called by muse, mutect2, varscan2
- DKK3 | c.221C>G p.A74G | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV100485160; called by muse, mutect2, varscan2
- DLX2 | c.821C>G p.S274W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV52231942; called by muse, mutect2, varscan2
- DNAAF2 | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs746751400, COSV53568701; called by muse, mutect2, varscan2
- DNAH1 | c.3137C>G p.S1046C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV70228160; called by muse, mutect2, varscan2
- DNAH11 | c.5701G>C p.E1901Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60966494, COSV60986317; called by muse, mutect2, varscan2
- DNAH3 | c.9322G>A p.D3108N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54515747; called by muse, mutect2, varscan2
- DNAH7 | c.7000C>G p.R2334G | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.985); catalogued as COSV56760084; called by muse, mutect2, varscan2
- DNAI3 | c.1094G>C p.R365T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54001885; called by muse, mutect2, varscan2
- DNAJC13 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV53449044; called by muse, mutect2
- DNTTIP2 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV63283934; called by muse, mutect2, varscan2
- DOCK11 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV52237184; called by muse, mutect2, varscan2
- DOCK3 | c.4429G>C p.E1477Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV56515278; called by muse, varscan2
- DOCK3 | c.4494G>C p.R1498S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.314); catalogued as COSV56515297, COSV56541419; called by muse, varscan2
- DOCK3 | c.5986G>C p.E1996Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.035); catalogued as COSV56515321; called by muse, varscan2
- DOCK3 | c.6002G>C p.R2001P | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); catalogued as rs766138853; called by muse, varscan2
- DOCK4 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as COSV70313634; called by muse, mutect2, varscan2
- DOCK8 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs368637845, COSV66632922; called by muse, mutect2, varscan2
- DOCK8 | c.2632C>G p.R878G | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV101210119; called by muse, varscan2
- DOCK8 | c.4124G>C p.R1375T | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV66622410; called by muse, mutect2, varscan2
- DOCK8 | c.6085G>C p.E2029Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV66619313; called by muse, mutect2, varscan2
- DOK6 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV66929341, COSV66929913; called by muse, mutect2, varscan2
- DPPA4 | c.17C>G p.A6G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.042); catalogued as COSV59509958; called by muse, mutect2, varscan2
- DPRX | c.539C>G p.S180C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV64949370; called by muse, mutect2, varscan2
- DPYSL5 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.227); catalogued as rs1371523009, COSV56513067; called by muse, mutect2, varscan2
- DPYSL5 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56510779; called by muse, mutect2, varscan2
- DST | c.9764G>C p.R3255T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); catalogued as COSV54999380; called by muse, mutect2, varscan2
- DST | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100424973; called by muse, mutect2, varscan2
- DTNA | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV51999426; called by muse, mutect2, varscan2
- DUSP7 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); catalogued as COSV56588922; called by muse, mutect2, varscan2
- DYNC2H1 | c.5357G>A p.G1786E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62091874; called by muse, mutect2
- DYRK1A | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58293306; called by muse, mutect2, varscan2
- DZIP1 | c.2053G>A p.E685K (on ENST00000347108; = p.E666K on NM_014934.5) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs770171062, COSV61265165; called by muse, mutect2, varscan2
- E2F3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.119); catalogued as rs765868574, COSV60896645; called by muse, mutect2, varscan2
- E2F7 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV59744651; called by muse, mutect2, varscan2
- ECI1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57043306; called by muse, mutect2, varscan2
- EEF2 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV58579165; called by muse, mutect2, varscan2
- EFL1 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51604683; called by muse, mutect2, varscan2
- EHMT2 | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.4); catalogued as COSV57667339, COSV99999155; called by muse, mutect2, varscan2
- EIF2AK1 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1055053406, COSV52237789; called by muse, mutect2, varscan2
- EIF3C | c.801G>C p.K267N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.399); catalogued as COSV59060177; called by muse, mutect2, varscan2
- EIF4A1 | c.233C>A p.S78Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51510456, COSV51510463; called by muse, mutect2, varscan2
- EIF4G2 | c.753G>C p.L251F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60596630; called by muse, mutect2, varscan2
- ELP2 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV60851876; called by muse, mutect2, varscan2
- ENPP4 | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV58088756; called by muse, mutect2, varscan2
- ENPP7 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60386222; called by muse, mutect2, varscan2
- EOMES | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs141551851, COSV99842455; called by muse, mutect2, varscan2
- EP400 | c.4384C>G p.P1462A | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as COSV57772725; called by muse, mutect2, varscan2
- EPC1 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs1160628199, COSV53924919; called by muse, mutect2, varscan2
- EPG5 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.359); catalogued as rs1182334611; called by muse, mutect2, varscan2
- EPHA2 | c.2269G>C p.D757H | Missense Mutation (SNP) | VAF 83/106 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626297; called by muse, mutect2, varscan2
- EPHA2 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368150751; called by muse, mutect2, varscan2
- EPHA3 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867931903, COSV60696098; called by muse, mutect2
- EPHA5 | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV56640181; called by muse, mutect2, varscan2
- EPHA7 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV65181042; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.37); catalogued as COSV51616801; called by muse, mutect2, varscan2
- EPPK1 | c.4539G>C p.E1513D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV73261060; called by muse, mutect2
- EPPK1 | c.2102C>G p.S701C | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782199244; called by muse, mutect2, varscan2
- ERCC3 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs1251238422; called by muse, mutect2, varscan2
- ERCC6L2 | c.95G>C p.G32A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs770701064, COSV56629803; called by muse, mutect2, varscan2
- ERCC8 | c.75G>A p.R25= | Splice Region (SNP) | VAF 17/42 reads (40%) | catalogued as rs755656702, COSV54017296; called by muse, mutect2, varscan2
- ERMN | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV68075162; called by muse, mutect2, varscan2
- ERN1 | c.2714G>C p.R905T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70500470; called by muse, mutect2, varscan2
- ESPL1 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs566763422, COSV57758766; called by muse, mutect2, varscan2
- ESRP1 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV64409029; called by muse, mutect2, varscan2
- EXOC6 | c.1945C>G p.H649D | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV53322826; called by muse, mutect2, varscan2
- EXOSC10 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV58664964; called by muse, mutect2, varscan2
- EZH1 | c.1905G>C p.K635N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70549154, COSV70549194, COSV70549454; called by muse, mutect2, varscan2
- FAHD1 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs751170172, COSV66899681; called by muse, mutect2, varscan2
- FAIM2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1196660690, COSV100277497, COSV57738873; called by muse, mutect2, varscan2
- FAM184A | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775538811, COSV58858888; called by mutect2, varscan2
- FAM193A | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV61192967; called by muse, mutect2, varscan2
- FAM3D | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV62559491; called by muse, mutect2, varscan2
- FAN1 | c.2650G>C p.E884Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV62950366, COSV62952410; called by muse, mutect2, varscan2
- FANCI | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV55525738; called by muse, mutect2, varscan2
- FARP1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60332721; called by muse, mutect2, varscan2
- FASTKD1 | c.1970G>C p.R657T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as rs758111477; called by muse, mutect2, varscan2
- FASTKD3 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV52942833; called by muse, mutect2, varscan2
- FAT2 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs752704380, COSV55817735; called by muse, mutect2, varscan2
- FAT3 | c.12772G>C p.G4258R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.261); catalogued as COSV99972722; called by muse, mutect2, varscan2
- FAT4 | c.6846G>A p.V2282= | Splice Region (SNP) | VAF 21/52 reads (40%) | catalogued as rs773018653, COSV100628538; called by muse, mutect2, varscan2
- FBLN1 | c.1788C>G p.I596M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV59937180; called by muse, mutect2, varscan2
- FBXL16 | c.300G>C p.K100N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60964307; called by muse, mutect2, varscan2
- FBXO40 | c.2007C>G p.F669L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57523420; called by muse, mutect2, varscan2
- FCGBP | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.98); PolyPhen benign (0.39); catalogued as rs761807647; called by muse, mutect2, varscan2
- FCRL2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.305); catalogued as COSV63833269; called by muse, mutect2, varscan2
- FCRL5 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV62516638; called by muse, mutect2, varscan2
- FCRL6 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as rs766961582, COSV58940815; called by muse, varscan2
- FEM1A | c.1339C>G p.Q447E | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.416); catalogued as COSV54163519; called by muse, mutect2, varscan2
- FEM1C | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.385); catalogued as COSV99174464; called by muse, mutect2, varscan2
- FGL1 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.93); PolyPhen benign (0.025); catalogued as COSV67712250; called by muse, mutect2, varscan2
- FIGN | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV60765667; called by muse, mutect2, varscan2
- FIP1L1 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.644); catalogued as COSV60995564; called by muse, mutect2, varscan2
- FKBP15 | c.2707G>C p.E903Q | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV53036829; called by muse, mutect2, varscan2
- FKBPL | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV64322661; called by muse, mutect2, varscan2
- FLG | c.7561G>A p.E2521K | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs756516055, COSV64240268; called by muse, mutect2, varscan2
- FLG2 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.047); catalogued as rs374118925, COSV66174028; called by muse, mutect2, varscan2
- FLI1 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs887724822, COSV55643927; called by muse, mutect2, varscan2
- FLNC | c.3830C>T p.A1277V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV57954191; called by muse, mutect2, varscan2
- FLNC | c.8160C>G p.F2720L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99972563; called by muse, mutect2, varscan2
- FLT1 | c.3416G>C p.R1139T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV99146699; called by muse, mutect2, varscan2
- FLT4 | c.3068G>C p.R1023T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56105048, COSV56108456; called by muse, varscan2
- FNDC4 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as COSV53021036; called by muse, mutect2, varscan2
- FOXM1 | c.2084C>G p.S695* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV61205837; called by muse, mutect2, varscan2
- FOXRED2 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs756741928, COSV53399894; called by muse, mutect2, varscan2
- FRAS1 | c.6970G>C p.E2324Q | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV53603877, COSV99355189; called by muse, mutect2
- FRAS1 | c.11752C>G p.L3918V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1163363982, COSV53603899; called by muse, varscan2
- FREM2 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.023); catalogued as rs1293306260; called by muse, mutect2, varscan2
- FRMD4B | c.2381C>G p.S794* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV68329503; called by muse, mutect2, varscan2
- FRMD4B | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV68329511; called by muse, mutect2, varscan2
- FSCN1 | c.366C>G p.F122L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61018527; called by muse, varscan2
- FSCN1 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV61017348; called by muse, varscan2
- FSD2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV58009511; called by muse, mutect2, varscan2
- FSTL3 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV51261520; called by muse, mutect2, varscan2
- FSTL5 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV60190161, COSV60217403; called by muse, mutect2, varscan2
- FXR1 | c.411G>C p.L137F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59762380; called by muse, mutect2
- GAB4 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68753554; called by muse, mutect2, varscan2
- GABRR1 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.911); catalogued as COSV101034070, COSV65619209; called by muse, mutect2, varscan2
- GAK | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58503983; called by muse, mutect2, varscan2
- GAL3ST1 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV58892334; called by muse, mutect2, varscan2
- GALK1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs1368649615, CM124972, CM124973, COSV56690452, COSV56692729; called by muse, mutect2, varscan2
- GALNT17 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV61150081, COSV61153484, COSV61171276; called by muse, mutect2, varscan2
- GALT | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 164/269 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV101122796; called by muse, mutect2, varscan2
- GAMT | c.393G>C p.G131= | Splice Region (SNP) | VAF 29/66 reads (44%) | catalogued as COSV99283090; called by muse, mutect2, varscan2
- GAN | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as COSV73720845; called by muse, mutect2, varscan2
- GAPVD1 | c.3613G>A p.E1205K (on ENST00000394104; = p.E1214K on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV52921224; called by muse, mutect2, varscan2
- GARRE1 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV55098380; called by muse, mutect2, varscan2
- GCC2 | c.2587G>C p.E863Q | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV59175599; called by muse, mutect2, varscan2
- GIMAP6 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV61033100, COSV61034789; called by muse, mutect2, varscan2
- GJB1 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as CD031051, CM973201; called by muse, mutect2, varscan2
- GLB1L | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs764386870, COSV55476153; called by muse, mutect2, varscan2
- GLDC | c.792C>G p.F264L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1554648121, COSV58678965; called by muse, mutect2, varscan2
- GLDN | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs375789151; called by muse, mutect2
- GLI2 | c.3391G>C p.E1131Q (on ENST00000361492 / NM_001374353.1; = p.E1148Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV58039544; called by muse, mutect2, varscan2
- GLIS3 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV60927523; called by muse, mutect2, varscan2
- GMEB1 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV53794022; called by muse, mutect2, varscan2
- GNS | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50694389; called by muse, mutect2, varscan2
- GOLGB1 | c.3366C>G p.I1122M | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV61464338; called by muse, mutect2, varscan2
- GOLGB1 | c.1158G>C p.K386N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.647); catalogued as COSV61464348; called by muse, mutect2, varscan2
- GON4L | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV55191640; called by muse, mutect2
- GPATCH3 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs746205141, COSV64651939; called by muse, mutect2, varscan2
- GPBP1 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.093); catalogued as COSV53311194; called by muse, mutect2, varscan2
- GPR149 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1244639815; called by muse, mutect2, varscan2
- GPR156 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV59939213; called by muse, mutect2, varscan2
- GPR63 | c.735G>C p.L245F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.111); catalogued as COSV57743264; called by muse, mutect2, varscan2
- GPS2 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); catalogued as COSV59748257, COSV59751338; called by muse, mutect2, varscan2
- GPX1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV69042790, COSV69043951; called by muse, mutect2, varscan2
- GPX1 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV101346344; called by muse, mutect2, varscan2
- GRIP1 | c.1435C>T p.P479S (on ENST00000359742 / NM_001379345.1; = p.P427S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV54020947; called by muse, mutect2, varscan2
- GSDMB | c.1205C>G p.S402C (on ENST00000418519 / NM_001165958.1; = p.S380C on NM_018530.2) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1191457180; called by muse, varscan2
- GSDMB | c.1168G>A p.E390K (on ENST00000418519 / NM_001165958.1; = p.E368K on NM_018530.2) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs765175493; called by muse, varscan2
- GSPT1 | c.328G>C p.E110Q (on ENST00000420576 / NM_001130007.2; = p.E248Q on NM_002094.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV70452580; called by muse, varscan2
- GSTA3 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as COSV52980340; called by muse, mutect2, varscan2
- GTDC1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1410736632; called by muse, mutect2, varscan2
- GUCY1A1 | c.935G>A p.R312K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.16); catalogued as rs761897078, COSV56649671, COSV56650951; called by muse, mutect2, varscan2
- GUCY1A2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs765520349, COSV56479357, COSV99976720; called by muse, mutect2, varscan2
- GUSB | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59221471; called by muse, mutect2, varscan2
- H2BC13 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV62440473, COSV62440942, COSV62441214; called by muse, mutect2, varscan2
- HAT1 | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1419408148, COSV51362188; called by muse, mutect2, varscan2
- HCAR2 | c.812C>G p.S271W | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61024742; called by muse, mutect2, varscan2
- HECTD1 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV65991196; called by muse, mutect2, varscan2
- HECTD1 | c.1189C>G p.Q397E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV67945883; called by muse, mutect2, varscan2
- HECTD3 | c.1073-1G>A p.X358_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | catalogued as COSV55799827, COSV99870341; called by muse, mutect2, varscan2
- HECW1 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as rs1375586963, COSV67826994; called by muse, mutect2, varscan2
- HERC1 | c.7031C>T p.S2344F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs1427972389, COSV71247223; called by muse, varscan2
- HEXIM2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV56236180; called by muse, varscan2
- HEXIM2 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.094); catalogued as COSV56236209; called by muse, varscan2
- HIF1A | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV60188850; called by muse, mutect2, varscan2
- HIGD2A | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV51257379; called by muse, mutect2, varscan2
- HK1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1332719473; called by muse, mutect2
- HLA-A | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs199474387, COSV100954343; called by muse, mutect2, varscan2
- HLA-B | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 39/56 reads (70%) | catalogued as rs151341205, COSV69520708; called by muse, mutect2
- HNRNPC | c.913G>A p.D305N (on ENST00000420743; = p.D292N on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV60144671; called by muse, mutect2, varscan2
- HNRNPR | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.86); PolyPhen benign (0.163); catalogued as COSV56421009; called by muse, mutect2, varscan2
- HOXC6 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as rs1440055649, COSV54536731; called by muse, mutect2, varscan2
- HPD | c.242-1G>T p.X81_splice | Splice Site (SNP) | VAF 34/86 reads (40%) | catalogued as COSV56641668, COSV56642546; called by muse, mutect2, varscan2
- HRC | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV53255567, COSV53255968; called by muse, mutect2, varscan2
- HSF1 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100183892, COSV60047530; called by muse, mutect2, varscan2
- HSPA1B | c.1704G>C p.K568N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs757789364, COSV65128403; called by muse, mutect2, varscan2
- HSPA2 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.906); catalogued as rs1437641293, COSV55969290; called by muse, mutect2, varscan2
- HSPG2 | c.6772G>A p.E2258K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs770242301, COSV65970742; called by muse, mutect2, varscan2
- HSPG2 | c.6131C>G p.S2044* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV101021042; called by muse, mutect2, varscan2
- HTT | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747789499, COSV61860510; called by muse, mutect2, varscan2
- HUWE1 | c.7003G>C p.E2335Q | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV53342192; called by muse, mutect2, varscan2
- ICE1 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV56822633; called by muse, mutect2, varscan2
- IDO2 | c.58C>G p.H20D (on ENST00000389060; = p.H33D on NM_194294.2) | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV58424877; called by muse, mutect2, varscan2
- IFI16 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99857593; called by muse, mutect2, varscan2
- IFITM3 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV67706932; called by muse, mutect2, varscan2
- IFT140 | c.4071C>G p.I1357M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.035); catalogued as COSV63697765; called by muse, mutect2, varscan2
- IFT74 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV66286552; called by muse, mutect2, varscan2
- IGF2BP1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV51730463; called by muse, mutect2, varscan2
- IGLV1-51 | c.182G>C p.G61A | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs781406572; called by muse, mutect2, varscan2
- IGSF1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0.18); catalogued as rs778830663, CD1211168, COSV100812485; called by muse, mutect2, varscan2
- IGSF11 | c.338C>G p.S113* (on ENST00000393775 / NM_001015887.3; = p.S112* on NM_152538.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV61168417; called by muse, mutect2, varscan2
- IGSF22 | c.2521G>A p.E841K (on ENST00000319338; = p.E942K on NM_173588.4) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.963); catalogued as COSV55010454; called by muse, mutect2, varscan2
- IL11 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1185331044, COSV52772468; called by muse, mutect2, varscan2
- IL12RB1 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59096819; called by muse, mutect2, varscan2
- IL18R1 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.342); catalogued as COSV52123967; called by muse, mutect2, varscan2
- IL21R | c.795G>C p.K265N | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV61969700; called by muse, mutect2, varscan2
- IMMP1L | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.819); catalogued as COSV53443852, COSV53446615; called by muse, mutect2, varscan2
- INF2 | c.2619C>G p.I873M | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as COSV53031758; called by muse, mutect2, varscan2
- ING5 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV100546089; called by muse, mutect2, varscan2
- INPP5B | c.227C>G p.S76W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV65958027; called by muse, mutect2, varscan2
- INSIG2 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 21/35 reads (60%) | catalogued as COSV55522350; called by muse, mutect2, varscan2
- INSR | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV57170998; called by muse, mutect2, varscan2
- INTS2 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV52152680; called by muse, mutect2, varscan2
- INTS3 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV59676762; called by muse, varscan2
- INVS | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV52440659; called by muse, mutect2
- INVS | c.2396G>A p.R799K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV52448165; called by muse, mutect2, varscan2
- IPO5 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV99847774; called by muse, mutect2, varscan2
- IQCA1 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs1043019454, COSV54499961; called by muse, mutect2, varscan2
- IRAG1 | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70210652; called by muse, mutect2, varscan2
- IRF2BP1 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56193317; called by muse, mutect2
- ITGA2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56858676; called by muse, mutect2
- ITGB1BP1 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV53005871; called by muse, mutect2, varscan2
- ITGB6 | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs751132914, COSV51790647, COSV99325115; called by muse, mutect2, varscan2
- ITPR1 | c.4725G>A p.M1575I (on ENST00000354582; = p.M1560I on NM_002222.7) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV56977420; called by muse, mutect2, varscan2
- ITPR2 | c.4870G>C p.E1624Q | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV67267910; called by muse, mutect2, varscan2
- ITPR3 | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs933450961, COSV65408018; called by muse, mutect2, varscan2
- ITPRID2 | c.2521C>G p.Q841E | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV57470916; called by muse, mutect2, varscan2
- ITSN1 | c.4711G>A p.E1571K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV67157067; called by muse, mutect2, varscan2
- JADE1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.685); catalogued as COSV56905352; called by muse, mutect2, varscan2
- JAG1 | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as COSV99068044; called by muse, mutect2, varscan2
- JAK3 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV71685925, COSV71688164; called by muse, mutect2, varscan2
- JARID2 | c.2592C>G p.H864Q | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV59188094; called by muse, mutect2, varscan2
- JAZF1 | c.190T>A p.F64I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52236091; called by muse, mutect2, varscan2
- JHY | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1386107510, COSV56218882; called by muse, mutect2, varscan2
- KALRN | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.995); catalogued as COSV53783199; called by muse, mutect2, varscan2
- KAZN | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs746895199, COSV63207642; called by muse, mutect2, varscan2
- KCNA6 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV54974759; called by muse, mutect2, varscan2
- KCNAB1 | c.409G>C p.D137H (on ENST00000490337 / NM_172160.3; = p.D126H on NM_003471.3) | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV56740340, COSV56742479; called by muse, mutect2, varscan2
- KCND2 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.037); catalogued as rs151258092, CM1413104; called by muse, mutect2, varscan2
- KCNE2 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV51710172; called by muse, mutect2, varscan2
- KCNJ9 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV63631652; called by muse, mutect2, varscan2
- KCNK2 | c.253C>G p.Q85E (on ENST00000444842 / NM_001017425.3; = p.Q70E on NM_014217.4) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV67208103; called by muse, mutect2, varscan2
- KCNQ3 | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.283); catalogued as COSV66468479; called by muse, mutect2
- KCNQ5 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372957711; called by muse, mutect2, varscan2
- KCTD18 | c.1147C>G p.P383A | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63344176; called by muse, mutect2, varscan2
- KDM3A | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57218911; called by muse, mutect2, varscan2
- KDM4D | c.348G>C p.Q116H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.232); catalogued as COSV58634340; called by muse, mutect2, varscan2
- KDM4D | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs782757194; called by muse, mutect2, varscan2
- KDM5A | c.4498G>C p.D1500H | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV66991811; called by muse, mutect2, varscan2
- KDM6B | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs201121189; called by muse, mutect2, varscan2
- KIAA0232 | c.1829C>G p.S610C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56924545; called by muse, mutect2, varscan2
- KIAA1109 | c.5401C>T p.Q1801* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV52669109; called by muse, mutect2
- KIAA1143 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56089044; called by muse, mutect2, varscan2
- KIAA1549 | c.5350C>G p.Q1784E | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.104); catalogued as COSV54311388, COSV99650761; called by muse, mutect2, varscan2
- KIDINS220 | c.3994G>C p.E1332Q | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); catalogued as COSV56752351; called by muse, mutect2, varscan2
- KIF1C | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.152); catalogued as rs377337240; called by muse, mutect2, varscan2
- KIF1C | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100297222; called by muse, mutect2, varscan2
- KIF20B | c.5314C>G p.Q1772E (on ENST00000371728 / NM_001284259.2; = p.Q1732E on NM_016195.4) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1286037544, COSV53305576; called by muse, mutect2, varscan2
- KIF22 | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.058); catalogued as rs1476270968, COSV50714615, COSV50715708; called by muse, mutect2
- KIF26B | c.4045G>A p.D1349N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV63639965; called by muse, mutect2, varscan2
- KIF4A | c.2911G>C p.E971Q | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV65542630; called by muse, mutect2, varscan2
- KLC2 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as rs775162419; called by muse, mutect2, varscan2
- KLHL15 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV60139955; called by muse, mutect2, varscan2
- KLHL3 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV59053588; called by muse, mutect2, varscan2
- KLHL6 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV58065258; called by muse, mutect2, varscan2
- KMT2A | c.6136C>T p.P2046S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63284578; called by muse, mutect2, varscan2
- KMT2A | c.8967G>A p.M2989I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs781817780, COSV63284522; ClinVar: benign; called by muse, mutect2, varscan2
- KMT2C | c.9897G>A p.M3299I | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV51280877, COSV51493900; called by muse, mutect2, varscan2
- KMT2D | c.15835G>T p.D5279Y | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56445329; called by muse, mutect2, varscan2
- KPNA1 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.175); catalogued as COSV60268514; called by muse, mutect2, varscan2
- KRBA1 | c.569G>C p.R190T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV55441021; called by muse, mutect2, varscan2
- KRT39 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 23/42 reads (55%) | catalogued as COSV62916783; called by muse, mutect2, varscan2
- KRT76 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as COSV60119868; called by muse, varscan2
- KTN1 | c.2757G>C p.L919F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs773402721, COSV63215555; called by muse, mutect2, varscan2
- L3MBTL2 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV53432744; called by muse, varscan2
- LAMC3 | c.4372G>A p.E1458K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs768009575, COSV62653966; called by muse, mutect2, varscan2
- LARGE1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as rs1385993432, COSV61659112; called by muse, mutect2, varscan2
- LCP2 | c.522C>T p.I174= | Splice Region (SNP) | VAF 42/103 reads (41%) | catalogued as rs367557459; called by muse, mutect2, varscan2
- LEPR | c.221C>G p.S74* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV60752105; called by muse, mutect2, varscan2
- LGALS3BP | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV53164699; called by muse, mutect2, varscan2
- LIG3 | c.2453C>G p.S818C | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52007014; called by muse, mutect2, varscan2
- LIG4 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV63596836; called by muse, mutect2, varscan2
- LILRA2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV52190474; called by muse, mutect2, varscan2
- LIN37 | c.32C>G p.S11* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV99494895; called by muse, mutect2, varscan2
- LINGO4 | c.1735G>C p.G579R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV64313692; called by muse, mutect2, varscan2
- LMNTD1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV51446148, COSV51446591; called by muse, mutect2, varscan2
- LONP2 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53521809; called by muse, mutect2, varscan2
- LPA | c.2827G>A p.G943R | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs369601677; called by muse, mutect2, varscan2
- LPP | c.1751G>A p.C584Y | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57086638; called by muse, mutect2, varscan2
- LRBA | c.3793G>T p.E1265* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100842234; called by muse, mutect2, varscan2
- LRCH1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100244033, COSV60846241; called by muse, mutect2, varscan2
- LRCH3 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV58391148; called by muse, mutect2, varscan2
- LRP12 | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV52634928; called by muse, mutect2, varscan2
- LRP1B | c.1521C>G p.F507L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV67206779, COSV67276651; called by muse, mutect2, varscan2
- LRP2 | c.1723G>C p.D575H | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55540600, COSV55549368; called by muse, mutect2, varscan2
- LRRC37A3 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.273); catalogued as COSV59760975; called by muse, mutect2, varscan2
- LRRFIP1 | c.448G>C p.E150Q (on ENST00000392000 / NM_001137552.2; = p.E278Q on NM_001137550.2) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1164011701, COSV55250699; called by muse, mutect2, varscan2
- LRRFIP1 | c.946G>C p.E316Q (on ENST00000392000 / NM_001137552.2; = p.E292Q on NM_004735.4) | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV55250715; called by muse, mutect2, varscan2
- LRRTM2 | c.161C>G p.S54* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV51219395, COSV51220596; called by muse, mutect2, varscan2
- LUC7L3 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV53586628, COSV53586759; called by muse, mutect2, varscan2
- MACF1 | c.3152C>T p.S1051L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV58369077; called by muse, mutect2, varscan2
- MADD | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV60622872; called by muse, mutect2, varscan2
- MAGEC1 | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV53569466, COSV53580714; called by muse, mutect2, varscan2
- MAGI3 | c.1286G>C p.R429T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56834513; called by muse, mutect2, varscan2
- MAML2 | c.2314C>T p.L772F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV73263191; called by muse, mutect2, varscan2
- MAP1LC3C | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1558179711; called by muse, mutect2
- MAP3K4 | c.4411C>G p.L1471V | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62332428; called by muse, mutect2, varscan2
- MAP4K3 | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99811308; called by muse, mutect2, varscan2
- MAP4K4 | c.3325C>G p.L1109V (on ENST00000347699 / NM_001242559.2; = p.L1027V on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.444); catalogued as COSV56335938; called by muse, mutect2, varscan2
- MAP4K5 | c.2273C>G p.S758* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV50153644; called by muse, mutect2, varscan2
- MAP4K5 | c.183G>C p.L61F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV50153683; called by muse, mutect2, varscan2
- MAPK9 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1221752065, COSV58121213; called by muse, mutect2, varscan2
- MARVELD2 | c.1470G>C p.M490I | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as COSV57780309, COSV57781638; called by muse, mutect2, varscan2
- MAST2 | c.2579C>G p.S860* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV63617585; called by muse, varscan2
- MATN2 | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.95); catalogued as rs1198540288; called by muse, mutect2, varscan2
- MB21D2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV66662850; called by muse, mutect2
- MBD6 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV63073987; called by muse, mutect2, varscan2
- MBD6 | c.1055C>G p.S352* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV63073994, COSV63076534; called by muse, varscan2
- MBD6 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV63073298; called by muse, varscan2
- MCF2L | c.1568C>A p.S523Y (on ENST00000375608; = p.S491Y on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.142); catalogued as COSV65050148; called by muse, mutect2, varscan2
- MCF2L | c.2962G>A p.E988K (on ENST00000375608; = p.E956K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as COSV56179839; called by muse, mutect2, varscan2
- MCL1 | c.485C>G p.S162W | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57190215; called by muse, mutect2, varscan2
- MDC1 | c.2942C>T p.S981L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV64524174; called by muse, mutect2, varscan2
- MDFIC | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs749315964; called by muse, mutect2, varscan2
- MED13 | c.5006G>T p.C1669F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV67263004; called by muse, mutect2, varscan2
- MED29 | c.225C>G p.F75L (on ENST00000615911; = p.F54L on NM_017592.4) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.992); catalogued as COSV55393426; called by muse, mutect2, varscan2
- MED30 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52067550; called by muse, mutect2, varscan2
- MET | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV59266308; called by muse, mutect2, varscan2
- MFAP1 | c.1295C>G p.S432C | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51038701; called by muse, mutect2, varscan2
- MGA | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV54952086; called by muse, mutect2, varscan2
- MINDY1 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as rs1481796100, COSV56498766; called by muse, mutect2, varscan2
- MKI67 | c.9608G>A p.R3203K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV100897105; called by muse, mutect2, varscan2
- MLIP | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | catalogued as COSV51428613; called by muse, mutect2, varscan2
- MLPH | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52819645; called by muse, mutect2, varscan2
- MMP19 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.189); catalogued as COSV59451119; called by muse, varscan2
- MMP19 | c.712C>G p.R238G | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV59451134; called by muse, mutect2, varscan2
- MMP20 | c.1112G>C p.R371T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV52775053; called by muse, mutect2, varscan2
- MMRN1 | c.2923A>T p.T975S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV53336307; called by muse, mutect2, varscan2
- MN1 | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV56557659; called by muse, mutect2, varscan2
- MORF4L1 | c.923G>A p.R308Q (on ENST00000331268 / NM_206839.2; = p.R269Q on NM_006791.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV58704239, COSV58706058; called by muse, mutect2, varscan2
- MOV10 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs778863602, COSV53517235; called by muse, mutect2, varscan2
- MRAS | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56671099, COSV56671155; called by muse, mutect2, varscan2
- MROH2B | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101270862; called by muse, mutect2, varscan2
- MRPS27 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.575); catalogued as COSV54650213; called by muse, mutect2, varscan2
- MRPS28 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 93/152 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52562069, COSV52563206; called by muse, varscan2
- MSH5 | c.2466G>C p.M822I | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV65173005; called by muse, mutect2, varscan2
- MST1 | c.735delinsTG p.D246Gfs*13 | Frame Shift Ins (INS) | VAF 48/169 reads (28%) | catalogued as COSV56532395, COSV56537231; called by mutect2*, pindel, varscan2*
- MTA2 | c.1197G>C p.K399N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53469629; called by muse, mutect2, varscan2
- MTDH | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); catalogued as rs1488308693, COSV60343599; called by muse, mutect2
- MTHFD2 | c.70C>G p.R24G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV51201263; called by muse, mutect2, varscan2
- MTOR | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV63870165; called by muse, mutect2, varscan2
- MTUS2 | c.1848G>C p.E616D | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV101462065; called by muse, mutect2, varscan2
- MUC17 | c.476C>G p.S159* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV60285773, COSV60300052; called by muse, mutect2, varscan2
- MUC17 | c.8299G>C p.E2767Q | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as COSV60285788; called by muse, mutect2, varscan2
- MUC20 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57848902; called by muse, mutect2, varscan2
- MYC | c.941C>T p.S314F (on ENST00000377970; = p.S329F on NM_002467.6) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); catalogued as COSV52371053; called by muse, mutect2, varscan2
- MYH10 | c.5881G>A p.E1961K | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV52607540; called by muse, mutect2, varscan2
- MYH10 | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52596421, COSV52598930; called by muse, mutect2, varscan2
- MYH15 | c.5593C>G p.Q1865E | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56308123; called by muse, mutect2, varscan2
- MYH3 | c.4712C>T p.S1571L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV56863557; called by muse, mutect2, varscan2
- MYL3 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs143852164, CM133978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1E | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55685426; called by muse, mutect2, varscan2
- MYO6 | c.2281G>C p.G761R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64118621; called by muse, mutect2, varscan2
- MYO9B | c.3694G>C p.E1232Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV68278426, COSV68278755; called by muse, mutect2, varscan2
- MYOC | c.192G>C p.Q64H | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV50674445, COSV50675911; called by muse, mutect2, varscan2
- N4BP1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV52212788; called by muse, mutect2, varscan2
- NAA25 | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55703651; called by muse, mutect2, varscan2
- NAV3 | c.3746G>A p.R1249Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs781607195, COSV57067298; called by mutect2, varscan2
- NAXE | c.662C>G p.S221* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV58039475; called by muse, mutect2, varscan2
- NCLN | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV55742324; called by muse, mutect2
- NCOA2 | c.4042C>G p.Q1348E | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51218804; called by muse, mutect2, varscan2
- NCOA5 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs1236679183, COSV99276195; called by muse, mutect2
- NCR1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99401258; called by muse, mutect2, varscan2
- NCR2 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); catalogued as COSV66100497; called by muse, mutect2, varscan2
- NDST3 | c.999G>C p.Q333H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV56617015; called by muse, mutect2, varscan2
- NEB | c.8332C>G p.P2778A | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV51465474; called by muse, mutect2, varscan2
- NEB | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.992); catalogued as rs1452109473, COSV99413342; called by muse, mutect2, varscan2
- NEB | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs753284331; called by muse, varscan2
- NEFH | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV60216446, COSV60216593; called by muse, mutect2, varscan2
- NEK10 | c.1115C>G p.S372* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV58282415; called by muse, mutect2, varscan2
- NEK8 | c.619-1G>C p.X207_splice | Splice Site (SNP) | VAF 22/41 reads (54%) | catalogued as COSV52044345; called by muse, mutect2, varscan2
- NEMF | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53594247; called by muse, mutect2, varscan2
- NEPRO | c.1310C>G p.S437* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs1249009081, COSV55605773; called by muse, mutect2
- NES | c.3436G>C p.E1146Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV63960765; called by muse, mutect2, varscan2
- NES | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.07); catalogued as rs767492510, COSV63960770, COSV63963471; called by muse, mutect2, varscan2
- NEU1 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57666834; called by muse, mutect2, varscan2
- NFATC4 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51599078; called by muse, mutect2, varscan2
- NFE2L2 | c.1102G>C p.D368H | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67960874; called by muse, mutect2, varscan2
- NFE2L2 | c.798G>C p.L266F | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.467); catalogued as rs770882525, COSV67962190; called by muse, mutect2, varscan2
- NFE2L2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV67960475, COSV67960879; called by muse, mutect2, varscan2
- NFIL3 | c.987C>G p.I329M | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52683547; called by muse, mutect2, varscan2
- NFKBIE | c.445G>A p.E149K (on ENST00000275015; = p.E10K on NM_004556.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs1322332758; called by muse, mutect2, varscan2
- NFKBIZ | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.558); catalogued as COSV58199986; called by muse, mutect2, varscan2
- NHS | c.1867C>T p.Q623* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV66273762; called by muse, mutect2, varscan2
- NIFK | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | catalogued as COSV53534607; called by muse, mutect2, varscan2
- NIPAL1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.043); catalogued as COSV55006257; called by muse, mutect2, varscan2
- NKAPD1 | c.859G>C p.E287Q (on ENST00000280352 / NM_001082970.2; = p.E288Q on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV54777974, COSV99736426; called by muse, mutect2, varscan2
- NKAPL | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100642535, COSV59198755; called by muse, varscan2
- NLRC5 | c.3752C>T p.S1251L | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV99348218; called by muse, mutect2, varscan2
- NLRC5 | c.4925C>T p.S1642L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52653415; called by muse, mutect2, varscan2
- NLRP2 | c.2971C>T p.Q991* | Nonsense Mutation (SNP) | VAF 46/101 reads (46%) | catalogued as COSV99671732; called by muse, mutect2, varscan2
- NOC2L | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.225); catalogued as COSV58531804, COSV58534052; called by muse, mutect2, varscan2
- NOL8 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs746622958, COSV62634871; called by muse, mutect2, varscan2
- NOS2 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs762737593; called by muse, mutect2, varscan2
- NOTCH1 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562413261; ClinVar: not provided; called by muse, mutect2, varscan2
- NOVA1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV57475290; called by muse, mutect2, varscan2
- NPHS2 | c.685C>G p.R229G | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as CM141333, COSV62635208; called by muse, mutect2, varscan2
- NPIPB15 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs1162346514; called by muse, mutect2, varscan2
- NPY5R | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV58451176; called by muse, mutect2, varscan2
- NR1D1 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1411580161, COSV52842082; called by muse, mutect2, varscan2
- NR1I2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377629240; called by muse, mutect2, varscan2
- NRTN | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs371970077; called by muse, mutect2, varscan2
- NSD1 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV61786259; called by muse, mutect2, varscan2
- NSF | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV56574533; called by muse, mutect2, varscan2
- NT5DC2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs748148023, COSV58734882; called by muse, mutect2, varscan2
- NTRK3 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV58118043; called by muse, mutect2, varscan2
- NUP153 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50448266; called by muse, mutect2, varscan2
- NUP214 | c.2782C>G p.H928D | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV63908895; called by muse, mutect2
- NUP37 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51837526; called by muse, mutect2, varscan2
- NXPH2 | c.684C>G p.F228L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55641728; called by muse, varscan2
- NYNRIN | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs1566487207; called by muse, mutect2, varscan2
- OAZ3 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs776894094, COSV58617941; called by muse, mutect2, varscan2
- ODF4 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs140528575; called by muse, mutect2, varscan2
- OIT3 | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61825762; called by muse, mutect2, varscan2
- OMG | c.1285C>T p.L429F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV55987933; called by muse, mutect2, varscan2
- OR14C36 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV58600960, COSV58601720; called by muse, mutect2
- OR1L1 | c.1067G>C p.R356T (on ENST00000373686; = p.R306T on NM_001005236.3) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV58935480; called by muse, mutect2, varscan2
- OR2A2 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.219); catalogued as COSV101286667, COSV68871403; called by muse, mutect2, varscan2
- OR2B3 | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101013851, COSV65850873; called by muse, mutect2, varscan2
- OR3A3 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52167252, COSV52168343; called by muse, mutect2, varscan2
- OR4C3 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.381); catalogued as COSV60589837; called by muse, varscan2
- OR4D11 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs767134245, COSV57585377; called by muse, mutect2, varscan2
- OR4F15 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as COSV59968765; called by muse, mutect2, varscan2
- OR52N5 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57698713; called by muse, mutect2, varscan2
- OR5L1 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61733555; called by muse, mutect2, varscan2
- OR5T3 | c.381G>C p.L127F | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767696866, COSV57380156; called by muse, mutect2, varscan2
- OR8D4 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.113); catalogued as COSV58430083; called by muse, mutect2, varscan2
- OXSM | c.656C>G p.S219* | Nonsense Mutation (SNP) | VAF 34/85 reads (40%) | catalogued as COSV55001089; called by muse, mutect2, varscan2
- P4HA2 | c.713C>G p.P238R | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV51324508; called by muse, mutect2, varscan2
- PAMR1 | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53511280; called by muse, mutect2, varscan2
- PCDH19 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM149757; called by muse, mutect2, varscan2
- PCDHA11 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1562636229; called by muse, mutect2, varscan2
- PCDHB2 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs782639355; called by muse, mutect2, varscan2
- PCDHB7 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV104370657, COSV50761842; called by muse, mutect2
- PCDHB7 | c.1257C>G p.I419M | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV50757338; called by muse, mutect2
- PCDHGA3 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV53929564; called by muse, mutect2, varscan2
- PCDHGA6 | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.145); catalogued as rs747224962, COSV53929580; called by muse, mutect2, varscan2
- PCDHGA8 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs763455922; called by muse, mutect2, varscan2
- PCDHGB6 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV53929603, COSV54048235; called by muse, mutect2, varscan2
- PCNT | c.4330G>C p.E1444Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV64033225; called by muse, mutect2, varscan2
- PCNX2 | c.2068G>C p.E690Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV50793336; called by muse, mutect2, varscan2
- PCNX2 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as COSV50793378; called by muse, mutect2, varscan2
- PCOLCE2 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV56001176; called by muse, mutect2
- PDCD2L | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV55826676; called by muse, mutect2, varscan2
- PDE4A | c.1420G>A p.D474N (on ENST00000380702 / NM_001111307.2; = p.D235N on NM_006202.3) | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53353843; called by muse, mutect2, varscan2
- PDE5A | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1238998646; called by muse, mutect2, varscan2
- PDHX | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs1057254984, COSV57165504; called by muse, mutect2, varscan2
- PDIA5 | c.1134G>A p.W378* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV60248519, COSV60251610; called by muse, mutect2
- PDLIM7 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100730222, COSV62883173; called by muse, mutect2, varscan2
- PDLIM7 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs376862538; called by muse, mutect2, varscan2
- PDSS2 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV64647439; called by muse, varscan2
- PDZD2 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56856150; called by muse, mutect2, varscan2
1,508 further variants in this file (918 protein-altering or splice-affecting, 532 silent, 58 other) are not listed here.
